CCDI case PBBWUH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5795e7e0-5c7e-4bda-bfc9-4366075b8422

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,538 days).

Biospecimens (3 samples)
- Sample 0DJ9ZX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJA01: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJA09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
